HCMI case HCM-WCMC-0671-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/603035e9-eef7-490a-a102-af4eb005fb73

Demographics
Sex at birth: female; Race: white; Year of birth: 1970.

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 47.4 years (17,322 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4a; AJCC pathologic N: N1c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: XELOX; Days to treatment start: 46 days; Days to treatment end: 88 days.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (2 entries)
- Days to follow up: 1,544 days (4.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 88.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CEA: 0.7 ng/mL.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gly12Ser.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PIK3CA mutation, nos: Negative.
- PMS2 (IHC): Positive.
- PTEN mutation, nos: Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 172.7 cm; BMI: 20.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0671-C18-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0671-C18-01A-S1-HE: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 76; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 45; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-0671-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0671-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 9.
- Sample HCM-WCMC-0671-C18-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
